Somatic mutation profile of tumor specimen TCGA-XH-A853-01A (aliquot TCGA-XH-A853-01A-11D-A423-09) from TCGA case TCGA-XH-A853, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 67.2 years (24,556 days).
Specimen TCGA-XH-A853-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b871685f-91fa-430b-a9d6-b688dbcbdb68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XH-A853-10A (Blood Derived Normal), aliquot TCGA-XH-A853-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fb70ba5-7eb8-49f0-b1b8-928de222103a

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 18/518 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CEP250 | c.2432T>C p.L811P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PI15 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PLPP3 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RIMBP2 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2
